Gene-level copy-number profile of tumor specimen TCGA-TQ-A7RK-01A from TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.4 years (10,742 days).
Specimen TCGA-TQ-A7RK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.2410fa28-17d2-4e9f-be70-a93939465327.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A7RK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97831a07-de51-4dc2-b059-b45c032cdcc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,201; copy number 2: 53,086; copy number 3: 1,789; copy number 4: 488; copy number 5: 252.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TQ-A7RK-01A-11D-A33S-01): tumor purity 0.65, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 252 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:61,865,367–61,928,016, 1 gene, copy number 5 (within-gene range 3–5): INTS2.
- chr17:61,942,605–72,058,073, 250 genes, copy number 5 (broad region; genes not listed).
- chr17:72,072,333–72,103,035, 1 gene, copy number 5 (within-gene range 4–5): LINC02097.

Autosomal genes at a single copy (total copy number 1): 1,821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
